Somatic mutation profile of tumor specimen TCGA-2G-AAGO-01A (aliquot TCGA-2G-AAGO-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAGO, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 41.9 years (15,300 days).
Specimen TCGA-2G-AAGO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dde09e9a-7670-4d23-a049-8c0d9700f329.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGO-10A (Blood Derived Normal), aliquot TCGA-2G-AAGO-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c993608-f4e6-4484-8981-0c7652e5bac0

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Intron 2, Frame Shift Del 2, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRB1 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65167681; called by muse, mutect2
- DIS3L2 | c.1922A>G p.N641S | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.02); catalogued as rs769948942; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HK3 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.666); catalogued as COSV52842900; called by muse, mutect2
- NKX2-5 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.151); catalogued as COSV61299591; called by muse, mutect2, varscan2
- PDPK1 | c.1588G>A p.G530R | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.429); catalogued as COSV51912351; called by muse, mutect2, varscan2
- PKHD1 | c.11315G>A p.R3772Q | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs759404490; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- ADAMTSL4 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADSS2 | c.268A>G p.N90D | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAMKV | c.153_161del p.C52_K54del | In Frame Del (DEL) | VAF 25/80 reads (31%) | called by mutect2, pindel, varscan2
- DENND1A | c.2690G>A p.G897D | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- DYSF | c.2156G>T p.G719V | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- GRB14 | c.1277G>T p.S426I | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HDAC10 | c.546_549del p.F183Rfs*133 | Frame Shift Del (DEL) | VAF 14/65 reads (22%) | called by mutect2, pindel, varscan2
- IRAK1BP1 | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEB10 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- MYO18A | c.6136G>A p.E2046K | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OTUD3 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RABEP2 | c.549T>G p.R183= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- SDAD1 | c.1269C>T p.H423= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as rs143777133; called by muse, mutect2, varscan2
- SPATA31D1 | c.3807G>A p.K1269= | Silent (SNP) | VAF 28/84 reads (33%) | called by muse, mutect2, varscan2
- LRRC23 | c.621+21G>A | Intron (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- UQCR10 | c.150+20C>T | Intron (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
